Gene-level copy-number profile of tumor specimen TCGA-DX-A3UF-01A from TCGA case TCGA-DX-A3UF, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 65.7 years (23,993 days).
Specimen TCGA-DX-A3UF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.ae0fe7b8-3e13-4418-8e42-1d1572e6936b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3UF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b59c6eca-6d42-4723-ac40-acbdac4ff9bf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,867; copy number 2: 15,659; copy number 3: 9,939; copy number 4: 22,524; copy number 5: 7,795; copy number 6: 1,121; copy number 7: 366; copy number 8: 48; copy number 9: 39; copy number 10: 105; copy number 11: 30; copy number 12: 306; copy number 13: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3UF-01A-11D-A306-01): tumor purity 0.88, ploidy 1.7, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,867. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
